Somatic mutation profile of tumor specimen 0DL1TN from CCDI case PBBYWT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.3 years (464 days).
Specimen 0DL1TN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9070caa4-0dd6-4d78-a1c2-acb8dafaefb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL1T1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6736c559-6191-42a0-ab78-647b522be8bc

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQCD | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 86/696 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149207555; called by muse, mutect2, varscan2
- SYNDIG1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 36/530 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs778443324, COSV100965292, COSV65237741; called by muse, mutect2
- OR9G4 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 122/1300 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2
- NRXN3 | c.1395G>A p.R465= | Silent (SNP) | VAF 378/1012 reads (37%) | catalogued as rs1475235614; called by muse, mutect2, varscan2
